Gene-level copy-number profile of tumor specimen TCGA-96-7544-01A from TCGA case TCGA-96-7544, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.6 years (30,548 days).
Specimen TCGA-96-7544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1b5538d7-a773-4ab5-b47d-7e5a8ff7b43f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-96-7544-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c3d3a3af-d856-4f39-ad01-62ed3345e5df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 182; copy number 1: 20,126; copy number 2: 32,225; copy number 3: 5,317; copy number 4: 1,325; copy number 5: 603; copy number 9: 26; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-96-7544-01A-11D-2041-01): tumor purity 0.58, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 180 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr3:75,906,695–77,649,964, 1 gene (within-gene range 0–1): ROBO2.
- chr3:76,434,018–90,261,708, 88 genes (broad region; genes not listed).
- chr4:186,026,456–190,092,279, 83 genes (broad region; genes not listed).
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 631 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,644,717, 375 genes, copy number 5 (broad region; genes not listed).
- chr2:207,074,137–210,679,107, 72 genes, copy number 5 (broad region; genes not listed).
- chr6:121,079,494–125,445,193, 44 genes, copy number 5: TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1.
- chr6:140,158,591–142,681,267, 21 genes, copy number 5–12: RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24, AL035446.1, AL357084.1, AL357080.1, AL355596.2, AL355596.1, RN7SKP106, RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL355337.1.
- chr8:38,105,493–38,704,855, 25 genes, copy number 9: ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:38,744,020–38,744,131, 1 gene, copy number 9: Y_RNA.
- chr17:74,417,594–76,072,517, 93 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,711. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
